Somatic mutation profile of tumor specimen TARGET-30-PAVCGD-01A (aliquot TARGET-30-PAVCGD-01A-01D) from TARGET case TARGET-30-PAVCGD, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 3.3 years (1,198 days).
Specimen TARGET-30-PAVCGD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b80916d0-3111-46f1-9fe5-46ddc899c821.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAVCGD-10A (Blood Derived Normal), aliquot TARGET-30-PAVCGD-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe7f46a9-4a1e-4062-9bd7-4c5926905e79

The open-access MAF lists 12 somatic variants for this specimen: 3 protein-altering or splice-affecting, 4 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 5, Silent 4, Missense Mutation 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATRX | c.1925del p.N642Mfs*7 | Frame Shift Del (DEL) | VAF 83/253 reads (33%) | catalogued as COSV64872889; called by mutect2, pindel, varscan2
- ZNF469 | c.2312dup p.G772Wfs*66 | Frame Shift Ins (INS) | VAF 5/36 reads (14%) | catalogued as rs1157794985; called by mutect2, pindel, varscan2
- FLT4 | c.236G>T p.G79V | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT tolerated (0.69); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC168 | c.4914T>C p.S1638= | Silent (SNP) | VAF 71/218 reads (33%) | catalogued as COSV70555401; called by muse, mutect2, varscan2
- FCGBP | c.6834C>A p.P2278= | Silent (SNP) | VAF 30/214 reads (14%) | called by muse, mutect2, varscan2
- HERC1 | c.12924A>G p.S4308= | Silent (SNP) | VAF 29/189 reads (15%) | called by muse, mutect2, varscan2
- SUSD2 | c.2172C>T p.S724= | Silent (SNP) | VAF 6/65 reads (9%) | called by muse, mutect2, varscan2
- ARFGEF3 | c.*2750A>T | 3'UTR (SNP) | VAF 19/167 reads (11%) | called by muse, mutect2, varscan2
- ATN1 | c.*477C>T | 3'UTR (SNP) | VAF 7/46 reads (15%) | catalogued as rs1374968463; called by muse, mutect2, varscan2
- NCAM1 | c.*1501del | 3'UTR (DEL) | VAF 32/90 reads (36%) | catalogued as rs1170739632; called by mutect2, varscan2
- REPS2 | c.*2760C>A | 3'UTR (SNP) | VAF 20/234 reads (9%) | called by muse, mutect2
- TIAM1 | c.*1351dup | 3'UTR (INS) | VAF 15/157 reads (10%) | called by mutect2, pindel
